Somatic mutation profile of tumor specimen TCGA-13-0910-01A (aliquot TCGA-13-0910-01A-01W-0420-08) from TCGA case TCGA-13-0910, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.8 years (21,473 days).
Specimen TCGA-13-0910-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 057a79c6-86b4-4e32-94fe-ce99ba1094fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0910-10A (Blood Derived Normal), aliquot TCGA-13-0910-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/074eb2bd-867c-405e-a25e-af06c05e6f37

The open-access MAF lists 44 somatic variants for this specimen: 38 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 32, Silent 6, Frame Shift Ins 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 43/68 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.4016C>G p.A1339G | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV67134156; called by muse, mutect2, varscan2
- ADGRV1 | c.1787T>A p.L596* | Nonsense Mutation (SNP) | VAF 63/138 reads (46%) | catalogued as COSV67988712; called by muse, mutect2, varscan2
- ADRA2B | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1169533868, COSV69787749; called by muse, mutect2, varscan2
- ARHGAP35 | c.1467_1468del p.E490Rfs*15 | Frame Shift Del (DEL) | VAF 16/73 reads (22%) | catalogued as COSV68331685; called by mutect2, pindel, varscan2
- ARMC12 | c.491C>T p.T164M (on ENST00000373866 / NM_001286574.2; = p.T191M on NM_145028.5) | Missense Mutation (SNP) | VAF 283/398 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs372805979; called by muse, mutect2, varscan2
- ARNTL2 | c.967T>C p.W323R | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53826809; called by muse, mutect2, varscan2
- ASCC3 | c.4846A>G p.I1616V | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as rs753875786, COSV64977162; called by muse, mutect2, varscan2
- B4GALT2 | c.761T>G p.F254C | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58844441; called by muse, mutect2, varscan2
- BCHE | c.1395G>T p.M465I | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.059); catalogued as COSV52258509; called by muse, mutect2, varscan2
- CD1D | c.737A>G p.Q246R | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.273); catalogued as COSV100939563; called by muse, mutect2
- CDC14B | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99685401; called by muse, mutect2
- CFAP46 | c.7142G>T p.R2381I | Missense Mutation (SNP) | VAF 20/233 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as COSV99584143; called by muse, mutect2
- HCRTR2 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs141639071, COSV63793586, COSV63794792; called by muse, mutect2, varscan2
- LTBP1 | c.2081C>T p.S694F (on ENST00000404816 / NM_206943.4; = p.S368F on NM_000627.4) | Missense Mutation (SNP) | VAF 108/241 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63191020; called by muse, mutect2, varscan2
- MED12L | c.6212C>T p.P2071L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.041); catalogued as COSV99851955; called by muse, mutect2, varscan2
- MS4A15 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 95/365 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs781231770, COSV61960993; called by muse, mutect2, varscan2
- MYH7B | c.2722C>T p.R908* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as rs749943398, COSV99482433; called by muse, mutect2, varscan2
- NRROS | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs776104305, COSV60746558; called by muse, mutect2, varscan2
- PFKFB4 | c.368dup p.H124Tfs*6 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | catalogued as rs1560171077; called by pindel, varscan2
- PRKAR1B | c.441T>G p.S147R | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV100816564; called by muse, mutect2, varscan2
- PRMT2 | c.485G>T p.R162I | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV99388550; called by muse, mutect2, varscan2
- PRSS55 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 111/445 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100153681, COSV60808651; called by muse, mutect2, varscan2
- PTPRO | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs752358724, COSV55512609; called by muse, mutect2, varscan2
- PYHIN1 | c.1353C>G p.F451L | Missense Mutation (SNP) | VAF 104/287 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV63722973; called by muse, mutect2, varscan2
- RAN | c.122-1G>A p.X41_splice | Splice Site (SNP) | VAF 4/85 reads (5%) | catalogued as COSV99619639; called by muse, mutect2
- RARS1 | c.1022G>C p.R341T | Missense Mutation (SNP) | VAF 124/323 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV51564447; called by muse, mutect2, varscan2
- RET | c.2340G>T p.K780N | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100392735; called by muse, mutect2, varscan2
- RIMBP2 | c.2602C>A p.P868T | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99898701; called by muse, mutect2
- SFMBT2 | c.2656G>T p.V886L | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV62811916; called by muse, mutect2, varscan2
- SLC4A2 | c.3071G>A p.R1024H | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1177021784, COSV99879603; called by muse, mutect2
- SLC66A1 | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 50/624 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100913181; called by muse, mutect2
- SYT2 | c.1257G>C p.K419N | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV100937125; called by muse, mutect2
- TCF21 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as rs760685056, COSV99399575; called by muse, mutect2, varscan2
- TOM1L1 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 229/315 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61948260; called by muse, mutect2, varscan2
- ZBTB21 | c.2755A>C p.T919P | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV60404706; called by muse, mutect2, varscan2
- ZNF384 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 166/974 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs968023019, COSV100158254; called by muse, varscan2
- JAK2 | c.2735dup p.Y913Vfs*12 | Frame Shift Ins (INS) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- ATP2B1 | c.3087A>G p.K1029= | Silent (SNP) | VAF 46/162 reads (28%) | catalogued as COSV53809518; called by muse, mutect2, varscan2
- KLHL32 | c.456C>T p.D152= | Silent (SNP) | VAF 65/185 reads (35%) | catalogued as rs1326091926, COSV65110839; called by muse, mutect2, varscan2
- LILRB4 | c.1239C>T p.Y413= (on ENST00000391733 / NM_001278428.3; = p.Y412= on NM_001278426.3) | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as rs191773308; called by muse, mutect2
- MED12L | c.5109C>T p.Y1703= | Silent (SNP) | VAF 52/226 reads (23%) | catalogued as rs767901074, COSV56377792; called by muse, mutect2, varscan2
- TRPC7 | c.504C>T p.I168= | Silent (SNP) | VAF 65/241 reads (27%) | catalogued as rs1178142311, COSV61462917; called by muse, mutect2, varscan2
- ZNF711 | c.714G>A p.G238= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV52156138; called by muse, mutect2, varscan2
